Somatic mutation profile of tumor specimen TCGA-BI-A0VR-01A (aliquot TCGA-BI-A0VR-01A-11D-A10S-08) from TCGA case TCGA-BI-A0VR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 53.3 years (19,473 days).
Specimen TCGA-BI-A0VR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86e5b32c-bf7c-41c0-bd55-6ae43fe61652.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BI-A0VR-10A (Blood Derived Normal), aliquot TCGA-BI-A0VR-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/150efea5-1ee8-4abb-8a74-8ae8204ee90f

The open-access MAF lists 140 somatic variants for this specimen: 96 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 41, Nonsense Mutation 4, Splice Region 2, In Frame Del 2, Intron 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 44/150 reads (29%) | catalogued as rs121909227, CM981672, COSV64290622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2823G>C p.L941F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.029); catalogued as COSV52225798; called by muse, mutect2, varscan2
- ACTN3 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as rs540771729, COSV59749566; called by muse, mutect2, varscan2
- AK7 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50875148; called by muse, mutect2, varscan2
- ANO9 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs1341728414, COSV60450239; called by muse, mutect2, varscan2
- ARID4A | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV62165090; called by muse, mutect2, varscan2
- ARVCF | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747415960, COSV54268154; called by muse, mutect2, varscan2
- ATG9B | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV52504781, COSV52506980; called by muse, mutect2, varscan2
- ATP13A4 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 6/161 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55071854; called by muse, mutect2
- B3GNT8 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.133); catalogued as COSV54198339; called by muse, mutect2
- BAIAP3 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136281; called by muse, mutect2
- CACNA2D2 | c.2375G>A p.R792H (on ENST00000479441 / NM_001174051.3; = p.R785H on NM_006030.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1011668282, COSV56562017; called by muse, mutect2
- CAMTA1 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 76/644 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV57911865; called by muse, mutect2, varscan2
- CCL20 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV62591513; called by muse, mutect2
- CEP250 | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV61171709; called by muse, mutect2
- CNTNAP1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1283843197, COSV52849254; called by muse, mutect2, varscan2
- CNTNAP4 | c.2200C>A p.Q734K | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.421); catalogued as COSV56689668; called by muse, varscan2
- CPLX4 | c.302A>C p.D101A | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as COSV55314098; called by muse, mutect2
- CPSF1 | c.3062C>T p.T1021M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs782156961, COSV58234425; called by muse, mutect2, varscan2
- CRYBG1 | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as rs1474161796, COSV64813101; called by muse, mutect2, varscan2
- CSMD2 | c.3214G>C p.E1072Q | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV53930880; called by muse, mutect2, varscan2
- CTNNA3 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV65600855; called by muse, mutect2, varscan2
- CUL4B | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV60689273; called by muse, mutect2
- CYB5R2 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.279); catalogued as COSV55086347; called by muse, mutect2, varscan2
- DDX3X | c.613G>T p.V205L (on ENST00000399959; = p.V206L on NM_001356.5) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV67863584, COSV67864022; called by muse, mutect2, varscan2
- DHX33 | c.998A>G p.Y333C | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as rs749610314, COSV56579869; called by muse, mutect2, varscan2
- DOCK11 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV52243093; called by muse, mutect2
- DYM | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV53988110; called by muse, mutect2
- DZIP1L | c.1206C>T p.I402= | Splice Region (SNP) | VAF 47/114 reads (41%) | catalogued as COSV59522164; called by muse, mutect2, varscan2
- EIF3E | c.222A>T p.R74S | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55204098; called by muse, mutect2, varscan2
- F2RL3 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs372809419, COSV50185898; called by muse, mutect2
- FRMPD2 | c.1671G>C p.R557S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV59719170, COSV59720094; called by muse, mutect2, varscan2
- FUT10 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV59452835; called by muse, mutect2, varscan2
- GABRA2 | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as COSV62916598, COSV62918140; called by muse, mutect2, varscan2
- GABRP | c.1002G>C p.Q334H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV54663974; called by muse, mutect2, varscan2
- GPBP1 | c.1228G>C p.D410H | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV53312809; called by muse, mutect2, varscan2
- GPKOW | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV50242421, COSV50243674; called by muse, mutect2, varscan2
- GPM6A | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54550046; called by muse, mutect2, varscan2
- HDAC8 | c.567C>G p.F189L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65239320; called by muse, mutect2
- HSPH1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs774955562, COSV60711756; called by muse, mutect2, varscan2
- IFI16 | c.2250G>C p.L750F (on ENST00000295809 / NM_001364867.2; = p.L694F on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55536340; called by muse, mutect2
- IFNAR1 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV54253058; called by muse, mutect2, varscan2
- JAKMIP3 | c.471G>C p.E157D | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53825699; called by muse, mutect2
- KCNMA1 | c.2588C>T p.P863L (on ENST00000286628 / NM_001161352.2; = p.P805L on NM_002247.4) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150678882; called by muse, mutect2, varscan2
- KIF3B | c.646C>G p.H216D | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65228264, COSV65228380; called by muse, mutect2
- LARS1 | c.1339G>A p.D447N (on ENST00000394434 / NM_020117.11; = p.D420N on NM_016460.3) | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV50980353; called by muse, mutect2, varscan2
- LRIG1 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1463555075, COSV56243654, COSV99834355; called by muse, mutect2, varscan2
- MARCHF6 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV56883651, COSV56884445; called by muse, mutect2, varscan2
- MARK2 | c.1541C>A p.S514Y (on ENST00000402010 / NM_001039469.2; = p.S480Y on NM_017490.4) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV59285770; called by muse, mutect2, varscan2
- MED31 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 38/151 reads (25%) | catalogued as COSV56726562; called by muse, mutect2, varscan2
- MS4A14 | c.1315G>T p.D439Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs925673784, COSV55736231; called by muse, mutect2, varscan2
- MTR | c.501C>T p.I167= | Splice Region (SNP) | VAF 27/118 reads (23%) | catalogued as COSV63968725; called by muse, mutect2, varscan2
- NFKBID | c.670C>T p.Q224* (on ENST00000396901; = p.Q376* on NM_032721.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 55/185 reads (30%) | catalogued as COSV61728971; called by muse, mutect2, varscan2
- NRCAM | c.1126G>A p.E376K (on ENST00000379028 / NM_001371124.1; = p.E370K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61041735; called by muse, mutect2, varscan2
- NUP58 | c.743C>G p.P248R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67751624; called by muse, mutect2, varscan2
- OAS1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV52537027; called by muse, mutect2, varscan2
- OIT3 | c.1296G>T p.L432F | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV61826046, COSV61826672; called by muse, mutect2, varscan2
- OR5D16 | c.627G>C p.E209D | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs767868149, COSV65722384; called by muse, mutect2, varscan2
- OR5W2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs148084259, COSV60615321; called by muse, mutect2, varscan2
- PANK3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV53321756; called by muse, mutect2
- PARN | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV58367937; called by muse, mutect2, varscan2
- PBX3 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as rs774888450, COSV60732643; called by muse, mutect2, varscan2
- PCDHA12 | c.1982C>A p.S661Y | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV56522049; called by muse, mutect2, varscan2
- PCSK4 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs527983571, COSV52013165, COSV52013571; called by muse, mutect2, varscan2
- PKHD1 | c.12128G>A p.S4043N | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV64394508; called by mutect2, varscan2
- PORCN | c.1168C>T p.R390C (on ENST00000326194 / NM_203475.3; = p.R379C on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV58226617; called by muse, mutect2
- PRUNE2 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV65043735; called by muse, mutect2, varscan2
- RPH3A | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66992002; called by muse, mutect2, varscan2
- SCARF1 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs780655556, COSV53959702; called by muse, mutect2, varscan2
- SDK1 | c.1179G>C p.E393D | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV67377959; called by muse, mutect2, varscan2
- SELENOT | c.109A>C p.T37P | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV101517717, COSV72000375; called by muse, mutect2
- SIPA1L1 | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1294493926, COSV62169355; called by muse, mutect2, varscan2
- SLC39A10 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as rs1302235471, COSV100660590, COSV62768221; called by muse, mutect2, varscan2
- SMC1A | c.859_861del p.K287del | In Frame Del (DEL) | VAF 22/91 reads (24%) | catalogued as rs1556890626; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SNTG2 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1285792310, COSV57975072, COSV57993535; called by muse, mutect2
- SPINK5 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs774381522, COSV56251791, COSV99806674; called by muse, mutect2
- STC1 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); catalogued as rs758995378, COSV51689073; called by muse, mutect2
- SYNE2 | c.14467G>C p.E4823Q | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV59956977; called by muse, mutect2
- TBC1D10A | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs201955996, COSV53164927; called by muse, mutect2, varscan2
- TDGF1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs765803584, COSV56127296; called by muse, mutect2, varscan2
- THSD1 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.931); catalogued as rs373901957; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2, varscan2
- TRIM59 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1003449582, COSV59087759; called by muse, mutect2
- TTN | c.52265T>C p.V17422A (on ENST00000591111; = p.V9998A on NM_003319.4) | Missense Mutation (SNP) | VAF 28/157 reads (18%) | PolyPhen probably damaging (0.99); catalogued as COSV60175730; called by muse, mutect2, varscan2
- TUFT1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.542); catalogued as COSV61949453; called by muse, mutect2, varscan2
- USP11 | c.2206G>C p.E736Q (on ENST00000218348; = p.E693Q on NM_001371072.1) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as COSV54474649; called by muse, mutect2
- UTP20 | c.5155G>A p.E1719K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.164); catalogued as COSV55380558; called by muse, mutect2, varscan2
- UTRN | c.7067A>G p.E2356G | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs754193488, COSV62340496; called by muse, mutect2
- UVRAG | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62104894, COSV62106583; called by muse, mutect2, varscan2
- XIRP2 | c.9247G>A p.A3083T (on ENST00000628543; = p.A3258T on NM_152381.6) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.161); catalogued as COSV54714305; called by muse, mutect2, varscan2
- XPOT | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs746325841, COSV60346544; called by muse, mutect2, varscan2
- ZNF776 | c.1226G>A p.C409Y | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57815754; called by muse, mutect2
- ZZEF1 | c.8195C>T p.S2732F | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV67558679; called by muse, mutect2
- COL3A1 | c.3770dup p.N1257Kfs*4 | Frame Shift Ins (INS) | VAF 13/102 reads (13%) | called by mutect2, pindel, varscan2
- GRM4 | c.649_657del p.K217_N219del | In Frame Del (DEL) | VAF 8/98 reads (8%) | called by mutect2, pindel
- TMEM185A | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADORA1 | c.408C>T p.F136= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs372315504; called by muse, mutect2, varscan2
- ALDH6A1 | c.861G>A p.K287= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV63246756; called by muse, varscan2
- BAIAP2L1 | c.336G>C p.V112= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV50057512; called by muse, mutect2
- BOC | c.1341G>A p.A447= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as rs766552892, COSV56354222; called by muse, mutect2
- BSND | c.21C>T p.F7= | Silent (SNP) | VAF 46/191 reads (24%) | catalogued as COSV64870921; called by muse, mutect2, varscan2
- CDH4 | c.2652C>T p.N884= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV64662520; called by muse, mutect2, varscan2
- CDK11B | c.1896G>A p.L632= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs767271491, COSV58339594; called by muse, mutect2
- CDK5R1 | c.417C>A p.P139= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV55579725; called by muse, mutect2, varscan2
- CETN1 | c.159G>A p.L53= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV59121447, COSV59121750; called by muse, mutect2, varscan2
- CMTM4 | c.321C>T p.L107= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV58063171; called by muse, mutect2, varscan2
- EGFL8 | c.786C>T p.I262= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as rs537573019, COSV61248134; called by muse, mutect2, varscan2
- FBXW9 | c.1356C>G p.L452= (on ENST00000587955; = p.L432= on NM_032301.3) | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV66710144, COSV66710383; called by muse, mutect2, varscan2
- FLVCR1 | c.483C>T p.I161= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs775427410, COSV63134365; called by muse, mutect2, varscan2
- GAB3 | c.408C>T p.S136= | Silent (SNP) | VAF 22/213 reads (10%) | catalogued as COSV65820118; called by muse, mutect2, varscan2
- HECW2 | c.4200G>A p.K1400= | Silent (SNP) | VAF 30/219 reads (14%) | catalogued as rs1559444396, COSV53665481; called by muse, mutect2, varscan2
- HUWE1 | c.12942C>T p.L4314= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as rs782813587, COSV53353975; called by muse, mutect2, varscan2
- IMPG2 | c.2098C>T p.L700= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as COSV51981508; called by muse, mutect2
- JARID2 | c.1509G>A p.T503= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1166677555, COSV59187979, COSV59194919; called by muse, mutect2, varscan2
- KCND2 | c.1173G>A p.S391= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs367909110; called by muse, mutect2, varscan2
- KDM6B | c.2412C>G p.L804= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV54678281, COSV54683781; called by muse, mutect2
- KIR2DL3 | c.771C>T p.F257= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs1324089272, COSV60898951; called by muse, mutect2, varscan2
- LHCGR | c.426G>A p.T142= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs142554296; called by muse, mutect2
- MASTL | c.255G>A p.L85= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV58760349; called by muse, mutect2
- MPP2 | c.1473C>T p.F491= (on ENST00000461854 / NM_001278372.2; = p.F467= on NM_005374.5) | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as COSV52237367; called by muse, mutect2, varscan2
- OPTC | c.945C>G p.L315= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV65868126; called by muse, mutect2, varscan2
- OR6C70 | c.432C>T p.F144= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV59245004; called by muse, mutect2, varscan2
- PDCD11 | c.4680G>A p.E1560= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV53296697; called by muse, varscan2
- PER3 | c.918G>A p.S306= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV62706710; called by muse, mutect2
- PGK1 | c.567G>A p.L189= | Silent (SNP) | VAF 19/273 reads (7%) | catalogued as COSV64832376; called by muse, mutect2
- PTPRN2 | c.1401C>T p.A467= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as rs772404937, COSV67046949; called by muse, mutect2, varscan2
- RNF214 | c.288A>C p.T96= | Silent (SNP) | VAF 21/155 reads (14%) | catalogued as COSV56119791; called by muse, mutect2, varscan2
- SCEL | c.921C>T p.I307= (on ENST00000349847 / NM_144777.3; = p.I287= on NM_003843.4) | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV62993993; called by muse, mutect2
- SDHA | c.1320G>A p.E440= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as COSV53767797; called by muse, varscan2
- SEMA5A | c.984G>A p.A328= | Silent (SNP) | VAF 19/218 reads (9%) | catalogued as rs1806117, COSV66791259, COSV66798891; called by muse, mutect2
- SETX | c.7275G>A p.L2425= | Silent (SNP) | VAF 25/498 reads (5%) | catalogued as COSV56389068; called by muse, mutect2
- SLC9A3 | c.1545C>T p.L515= | Silent (SNP) | VAF 11/196 reads (6%) | catalogued as rs1220775371, COSV53802676; called by muse, mutect2
- TASOR | c.3048T>C p.F1016= (on ENST00000355628 / NM_001365636.2; = p.F640= on NM_015224.3) | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV62928634; called by muse, mutect2, varscan2
- TNFRSF11A | c.219G>A p.P73= | Silent (SNP) | VAF 30/212 reads (14%) | catalogued as rs780909910, COSV54024687; called by muse, mutect2, varscan2
- TOP2A | c.2763T>C p.I921= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV70733114; called by muse, mutect2, varscan2
- TSC2 | c.741C>T p.I247= | Silent (SNP) | VAF 29/250 reads (12%) | catalogued as COSV54770793; called by muse, mutect2
- XYLT1 | c.1602G>A p.T534= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs138560456; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADSS1 | c.193-5007C>T | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as COSV58274696; called by muse, mutect2, varscan2
- QTRT2 | c.*2A>G | 3'UTR (SNP) | VAF 78/125 reads (62%) | catalogued as rs1559965688, COSV99846935; called by muse, mutect2, varscan2
- SHMT1 | c.243-90C>T | Intron (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
